Somatic mutation profile of tumor specimen MMRF_2268_1_BM_CD138pos (aliquot MMRF_2268_1_BM_CD138pos_T1_KHS5U_L11054) from MMRF case MMRF_2268, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.1 years (26,685 days).
Specimen MMRF_2268_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b30e7c9a-4296-4a88-a735-77d268eddaa1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2268_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2268_1_PB_WBC_C2_KHS5U_L11053; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97f9c14d-f0b4-46fe-b1d5-6af71bdf0804

The open-access MAF lists 26 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 10, Missense Mutation 4, Silent 4, 5'UTR 3, Intron 2, Nonsense Mutation 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A2 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 6/122 reads (5%) | catalogued as COSV51966295; called by muse, mutect2
- FOLR2 | c.-27C>T | Splice Region (SNP) | VAF 14/400 reads (4%) | called by muse, mutect2
- IK | c.488T>C p.V163A | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- LMAN1 | c.1129A>T p.M377L | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- MTUS1 | c.323T>G p.L108R | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); called by muse, mutect2
- NCK1 | c.710G>A p.G237D | Missense Mutation (SNP) | VAF 9/270 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC62 | c.1053A>C p.S351= | Silent (SNP) | VAF 8/157 reads (5%) | called by muse, mutect2
- GPR107 | c.1149C>T p.A383= | Silent (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- MFSD6L | c.69C>T p.C23= | Silent (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- TNFSF11 | c.690C>T p.D230= | Silent (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
- ARSD | c.*2896G>T | 3'UTR (SNP) | VAF 7/99 reads (7%) | called by muse, mutect2
- B4GALT6 | c.*2104C>T | 3'UTR (SNP) | VAF 3/37 reads (8%) | catalogued as rs1029974015; called by muse, mutect2
- CLCN3 | c.*2431A>T | 3'UTR (SNP) | VAF 5/89 reads (6%) | called by muse, mutect2
- CRAMP1 | c.*1934G>T | 3'UTR (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- DLX2 | c.-336G>A | 5'UTR (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- ENPP1 | c.*4551T>C | 3'UTR (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- GUCY2EP | n.1617C>T | RNA (SNP) | VAF 14/412 reads (3%) | catalogued as rs1372205051; called by muse, mutect2
- H2AC11 | c.*13G>C | 3'UTR (SNP) | VAF 32/576 reads (6%) | called by muse, mutect2
- HOXA1 | c.*864T>A | 3'UTR (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- LRRTM4 | c.1551+289T>A | Intron (SNP) | VAF 5/83 reads (6%) | catalogued as COSV69141786; called by muse, mutect2
- MX2 | c.-72+1973T>G | Intron (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- NPRL2 | c.-29G>A | 5'UTR (SNP) | VAF 18/352 reads (5%) | called by muse, mutect2
- OPRM1 | c.-250G>T | 5'UTR (SNP) | VAF 11/216 reads (5%) | called by muse, mutect2
- STAG1 | c.*481C>A | 3'UTR (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- TLCD4 | c.*5489G>T | 3'UTR (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- USP6NL | c.*1891T>A | 3'UTR (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
